Somatic mutation profile of cancer-model specimen HCM-SANG-0306-C15-85A (3D Organoid; aliquot HCM-SANG-0306-C15-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0306-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0306-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9075e51-276a-45d6-85ce-411e5f318a34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0306-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0306-C15-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0fef68e-463e-47b3-a308-6de8584a9b2a

The open-access MAF lists 222 somatic variants for this specimen: 143 protein-altering or splice-affecting, 39 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 39, Intron 23, Nonsense Mutation 10, RNA 7, Frame Shift Del 4, 5'UTR 3, Splice Region 3, Splice Site 3, 3'UTR 3, 5'Flank 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1B | c.215dup p.K73Qfs*52 | Frame Shift Ins (INS) | VAF 189/478 reads (40%) | catalogued as rs1555085549; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CEP164 | c.2689C>T p.R897* | Nonsense Mutation (SNP) | VAF 265/265 reads (100%) | catalogued as rs764893412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 65/65 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 104/105 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; called by muse, varscan2
- ABL1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs368646202; called by muse, mutect2
- ABL2 | c.2057C>T p.T686M (on ENST00000502732 / NM_007314.4; = p.T671M on NM_005158.5) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.63); catalogued as rs200298510, COSV61018832; called by muse, mutect2, varscan2
- ADRB3 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs1415275404; called by muse, mutect2, varscan2
- AFF2 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV53978708; called by muse, varscan2
- AHNAK2 | c.2923C>A p.L975M | Missense Mutation (SNP) | VAF 55/491 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV60906383; called by muse, mutect2, varscan2
- ALDH3A2 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 121/441 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51565585; called by muse, mutect2, varscan2
- APBA2 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 38/467 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.435); catalogued as COSV68796559; called by muse, mutect2
- ASXL1 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as rs531415735, COSV100037397; ClinVar: likely benign; called by muse, mutect2
- BHLHE22 | c.221_260del p.G74Afs*18 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs778657494; called by mutect2, pindel
- BRD9 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 171/684 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs752761624, COSV60248309; called by muse, mutect2, varscan2
- C16orf82 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763981866; called by muse, mutect2, varscan2
- C8orf34 | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs138458632; called by muse, mutect2, varscan2
- CABIN1 | c.3902G>T p.R1301M | Missense Mutation (SNP) | VAF 40/449 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54084350; called by muse, mutect2
- CDC7 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52311784; called by mutect2, varscan2
- CDH1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 142/240 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55727608, COSV55732475, COSV55742678; called by muse, mutect2, varscan2
- CHST12 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395609548; called by muse, mutect2
- CLK3 | c.1865G>T p.G622V (on ENST00000395066 / NM_001130028.1; = p.G474V on NM_003992.4) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV59341319; called by muse, mutect2
- CNTNAP4 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100273792; called by muse, mutect2, varscan2
- CRELD2 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1345873878; called by muse, mutect2, varscan2
- CUBN | c.4654T>G p.F1552V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV100913308; called by muse, mutect2
- DNAH5 | c.7634G>A p.R2545H | Missense Mutation (SNP) | VAF 28/666 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs139348927, COSV54222169; called by muse, mutect2
- DUOX1 | c.3409G>A p.A1137T | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1441615959; called by muse, mutect2, varscan2
- GBE1 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1245333229; called by muse, mutect2, varscan2
- GFRA1 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1286497178; called by muse, mutect2, varscan2
- GPR176 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777841556, COSV100137250; called by muse, mutect2, varscan2
- GRID2 | c.1246-2A>G p.X416_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56183264; called by muse, mutect2, varscan2
- GRIK3 | c.2566C>T p.R856C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1039838704, COSV66136255; called by muse, mutect2, varscan2
- GTF3C1 | c.5071G>A p.A1691T | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1310432497; called by muse, mutect2, varscan2
- HK3 | c.2104G>A p.V702M | Missense Mutation (SNP) | VAF 135/245 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs745716229, COSV52839351, COSV52839838; called by muse, mutect2, varscan2
- IGHV3-49 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 147/269 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.254); catalogued as rs201699005; called by muse, mutect2, varscan2
- IL1F10 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as rs776109569; called by muse, mutect2, varscan2
- INPP5E | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 35/604 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV65495847; called by muse, mutect2
- ITK | c.1514+1G>T p.X505_splice | Splice Site (SNP) | VAF 50/573 reads (9%) | catalogued as COSV101439655; called by muse, mutect2
- KMT2B | c.8134C>T p.R2712W | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53074445; called by muse, mutect2, varscan2
- KSR1 | c.1826G>A p.R609H (on ENST00000644974 / NM_001367810.1; = p.R494H on NM_014238.2) | Missense Mutation (SNP) | VAF 262/593 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs766513109; called by muse, mutect2, varscan2
- LPAR2 | c.591C>G p.S197R | Missense Mutation (SNP) | VAF 149/306 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV104390674; called by muse, mutect2, varscan2
- LRRIQ3 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs920479816, COSV63041854; called by muse, mutect2
- LTBP4 | c.1550G>A p.R517Q (on ENST00000308370 / NM_001042544.1; = p.R480Q on NM_003573.2) | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs759437621; called by muse, mutect2, varscan2
- MAGI2 | c.931G>C p.A311P | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62641925; called by muse, mutect2, varscan2
- MASP1 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV51457565, COSV51457956; called by muse, mutect2, varscan2
- MED23 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240522677; called by muse, mutect2
- MT1E | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV100042280; called by muse, mutect2, varscan2
- MTMR3 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs932469715; called by muse, mutect2
- NOS3 | c.2205C>A p.Y735* | Nonsense Mutation (SNP) | VAF 29/242 reads (12%) | catalogued as COSV52497066; called by muse, mutect2, varscan2
- NOX4 | c.978G>T p.M326I | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs780900491, COSV54451496; called by muse, mutect2, varscan2
- NUTM2A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323305462; called by mutect2, varscan2
- NXNL2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1202857180, COSV65474529; called by muse, mutect2
- OSCAR | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 163/372 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.334); catalogued as rs1230924585, COSV52927099; called by muse, mutect2, varscan2
- PDZD7 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426679303; called by muse, mutect2
- PRLR | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 33/544 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1490023814, COSV51493677; called by muse, mutect2
- PTCH1 | c.2396C>A p.S799Y | Missense Mutation (SNP) | VAF 112/176 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59498389; called by muse, mutect2, varscan2
- RAD51C | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99542853; called by muse, mutect2, varscan2
- RBMXL3 | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 24/226 reads (11%) | catalogued as rs967471072, COSV57752405; called by muse, mutect2, varscan2
- RIN1 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.011); catalogued as COSV60926153; called by muse, mutect2, varscan2
- RNASE13 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1337587788; called by muse, mutect2
- SLA | c.406C>T p.R136C (on ENST00000338087 / NM_001045556.3; = p.R176C on NM_006748.4) | Missense Mutation (SNP) | VAF 199/261 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200511116, COSV55065123; called by muse, mutect2, varscan2
- SLC22A24 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 27/291 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370756811; called by muse, mutect2, varscan2
- SLIT3 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV60593692; called by muse, mutect2
- SRSF8 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 63/536 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782051592; called by muse, mutect2, varscan2
- TCAF1 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs527857343; called by mutect2, varscan2
- THSD7A | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs767811878, COSV70260472; called by muse, mutect2
- TNN | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99078398; called by muse, mutect2, varscan2
- ULK2 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 180/963 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs145056970; called by muse, mutect2, varscan2
- USP8 | c.2107C>T p.P703S | Missense Mutation (SNP) | VAF 54/616 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV56166558; called by muse, mutect2
- VEGFD | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 108/147 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs370603238; called by muse, mutect2, varscan2
- ZBTB9 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs376615612; called by muse, mutect2
- ZNF528 | c.1343A>T p.E448V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.089); catalogued as rs765483309; called by muse, mutect2, varscan2
- ZNF681 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.66); PolyPhen benign (0.059); catalogued as rs958784107; called by muse, mutect2, varscan2
- ZNF770 | c.1254T>A p.N418K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs764870732; called by muse, mutect2, varscan2
- ADRA2C | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.355); called by muse, mutect2
- ANKMY1 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APLF | c.1184A>C p.H395P | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ASH1L | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BHLHE22 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- C16orf82 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CASKIN1 | c.3134_3170del p.A1045Gfs*4 | Frame Shift Del (DEL) | VAF 28/340 reads (8%) | called by mutect2, pindel
- CBX2 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 98/424 reads (23%) | called by muse, mutect2, varscan2
- CD40LG | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CDYL2 | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- CFHR3 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.345); called by muse, varscan2
- CHRM2 | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A3 | c.1273G>A p.G425S | Missense Mutation (SNP) | VAF 77/143 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPA3 | c.1235T>C p.I412T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CTAGE6 | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); called by muse, varscan2
- DCDC1 | c.4654G>T p.A1552S (on ENST00000597505 / NM_001367979.1; = p.A659S on NM_020869.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.293); called by muse, varscan2
- DIDO1 | c.1588+3A>G | Splice Region (SNP) | VAF 735/901 reads (82%) | called by muse, mutect2, varscan2
- DPP6 | c.1160A>T p.K387M (on ENST00000377770 / NM_001364500.2; = p.K325M on NM_001936.5) | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- DSCAML1 | c.880T>C p.S294P (on ENST00000321322; = p.S234P on NM_020693.4) | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DUOXA1 | c.44A>C p.K15T | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- F11 | c.11T>A p.L4* | Nonsense Mutation (SNP) | VAF 48/64 reads (75%) | called by muse, mutect2, varscan2
- FAM83H | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 60/658 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- FOXD4 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 114/1094 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GGA2 | c.1280C>G p.A427G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- H3C10 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HCN1 | c.1942A>C p.N648H | Missense Mutation (SNP) | VAF 78/1277 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.556); called by muse, mutect2
- IGKV2-28 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- KCNA6 | c.1366G>A p.V456I | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KCNV2 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP19-1 | c.235_236del p.S79Vfs*51 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | called by mutect2, pindel
- LRRC30 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LRRC30 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MAGEA6 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 201/360 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MKRN3 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 45/76 reads (59%) | called by mutect2, varscan2
- MYLK2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- NECTIN4 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NEXN | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR2V1 | c.698A>C p.Q233P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- OR52N2 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- OR5AC2 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- OTOGL | c.6270A>T p.G2090= (on ENST00000547103; = p.G2081= on NM_173591.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- PABPC5 | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAOX | c.1083C>G p.F361L | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, varscan2
- PHEX | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIEZO2 | c.8064C>G p.F2688L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PNLDC1 | c.1323G>T p.K441N | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PPP4R3C | c.2181G>T p.E727D | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PRKAG2 | c.1442T>G p.L481R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPTOR | c.1356G>T p.L452F | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SACS | c.9017T>G p.L3006W | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SCARB2 | c.1240-6C>T | Splice Region (SNP) | VAF 79/102 reads (77%) | called by muse, mutect2, varscan2
- SELPLG | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 281/481 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC15A4 | c.518C>G p.A173G | Missense Mutation (SNP) | VAF 131/215 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SLC30A4 | c.1124_1135del p.H375_I379delinsL | In Frame Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- SLC44A5 | c.1408T>C p.F470L | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLITRK2 | c.2488C>A p.P830T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1414G>T p.G472* | Nonsense Mutation (SNP) | VAF 56/368 reads (15%) | called by muse, mutect2, varscan2
- TLN2 | c.5412G>A p.M1804I | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TOB1 | c.918_919insATC p.A306_F307insI | In Frame Ins (INS) | VAF 19/186 reads (10%) | called by mutect2, pindel
- TP53BP1 | c.4940C>T p.T1647I | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRDN | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBR2 | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- UBR4 | c.5501G>A p.S1834N | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- UNC79 | c.2534del p.G845Dfs*34 (on ENST00000393151 / NM_001346218.2; = p.G668Dfs*34 on NM_020818.5) | Frame Shift Del (DEL) | VAF 33/178 reads (19%) | called by mutect2, pindel, varscan2
- VN1R2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2
- WDFY4 | c.8569C>T p.Q2857* | Nonsense Mutation (SNP) | VAF 80/110 reads (73%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.2591A>G p.K864R | Missense Mutation (SNP) | VAF 192/253 reads (76%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF160 | c.1634G>T p.S545I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNF782 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- ZNF830 | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ABRA | c.297T>C p.P99= | Silent (SNP) | VAF 46/498 reads (9%) | called by muse, mutect2
- ACSS3 | c.654G>C p.V218= | Silent (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- AMOT | c.1464C>T p.A488= (on ENST00000371959 / NM_001113490.1; = p.A79= on NM_133265.3) | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV59065852; called by muse, mutect2, varscan2
- ANKRD50 | c.1332C>T p.A444= | Silent (SNP) | VAF 40/51 reads (78%) | called by muse, mutect2, varscan2
- ART5 | c.660C>T p.R220= | Silent (SNP) | VAF 34/340 reads (10%) | catalogued as rs770807658, COSV63364243; called by muse, mutect2
- ATP13A4 | c.3177A>T p.G1059= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- CEP76 | c.1917T>G p.T639= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- COPS3 | c.280C>A p.R94= | Silent (SNP) | VAF 86/529 reads (16%) | called by muse, mutect2, varscan2
- FAM47C | c.258C>T p.P86= | Silent (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2, varscan2
- FMNL3 | c.1842G>A p.A614= | Silent (SNP) | VAF 44/506 reads (9%) | catalogued as rs778622208, COSV53298096; called by muse, mutect2
- GRIK2 | c.870C>A p.S290= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as COSV100024956; called by muse, mutect2
- HMX1 | c.585C>T p.G195= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as rs1214249906; called by muse, mutect2, varscan2
- HRNR | c.2163T>C p.S721= | Silent (SNP) | VAF 206/403 reads (51%) | called by muse, mutect2, varscan2
- HSD17B14 | c.408C>A p.V136= | Silent (SNP) | VAF 156/336 reads (46%) | called by muse, mutect2, varscan2
- IFI16 | c.498C>A p.S166= | Silent (SNP) | VAF 90/195 reads (46%) | catalogued as rs770141510; called by muse, mutect2, varscan2
- MN1 | c.222C>A p.G74= | Silent (SNP) | VAF 35/49 reads (71%) | called by muse, mutect2, varscan2
- MTCL1 | c.2067G>T p.G689= (on ENST00000306329 / NM_001378206.1; = p.G329= on NM_015210.4) | Silent (SNP) | VAF 28/255 reads (11%) | catalogued as COSV60405206; called by muse, mutect2, varscan2
- MYO6 | c.493C>T p.L165= | Silent (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- NME8 | c.523A>C p.R175= | Silent (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- NRXN3 | c.3070T>C p.L1024= (on ENST00000335750 / NM_001330195.2; = p.L651= on NM_004796.6) | Silent (SNP) | VAF 98/173 reads (57%) | catalogued as COSV59757414; called by muse, mutect2, varscan2
- PCDHA10 | c.1962C>T p.G654= | Silent (SNP) | VAF 129/129 reads (100%) | catalogued as rs1554151006, COSV100254244, COSV56478402; called by muse, mutect2, varscan2
- PCDHB9 | c.1326C>T p.S442= | Silent (SNP) | VAF 95/715 reads (13%) | catalogued as rs781968864, COSV53382232; called by muse, mutect2, varscan2
- PTCH1 | c.3390C>T p.A1130= | Silent (SNP) | VAF 262/390 reads (67%) | catalogued as rs762637887, COSV59486404; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM41 | c.672G>T p.V224= | Silent (SNP) | VAF 98/98 reads (100%) | called by muse, mutect2, varscan2
- RGS10 | c.18G>A p.V6= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, varscan2
- RGS9BP | c.120G>T p.L40= | Silent (SNP) | VAF 27/351 reads (8%) | catalogued as rs768692545; called by muse, mutect2
- SCN10A | c.5205C>A p.P1735= | Silent (SNP) | VAF 30/171 reads (18%) | catalogued as rs1008079839; called by muse, mutect2, varscan2
- SHOX2 | c.574A>C p.R192= (on ENST00000441443 / NM_006884.3; = p.R216= on NM_003030.4) | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- SLC47A1 | c.1539C>T p.G513= | Silent (SNP) | VAF 36/831 reads (4%) | catalogued as rs749378149, COSV54500570; called by muse, mutect2
- STARD9 | c.1953G>A p.Q651= | Silent (SNP) | VAF 82/226 reads (36%) | called by muse, mutect2, varscan2
- TFAP2C | c.387C>T p.S129= | Silent (SNP) | VAF 39/372 reads (10%) | catalogued as COSV52371982; called by muse, mutect2, varscan2
- THSD4 | c.309C>T p.H103= | Silent (SNP) | VAF 71/319 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.21363C>T p.L7121= (on ENST00000591111; = p.L6194= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV60146385; called by muse, mutect2, varscan2
- TXNIP | c.654C>T p.R218= | Silent (SNP) | VAF 154/289 reads (53%) | called by muse, mutect2, varscan2
- UNC79 | c.330C>T p.R110= | Silent (SNP) | VAF 26/344 reads (8%) | catalogued as rs1302515889; called by muse, mutect2
- USH2A | c.9582C>T p.N3194= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs764892257, COSV56412971; called by muse, mutect2
- USH2A | c.183A>C p.P61= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- VCAM1 | c.258T>C p.S86= | Silent (SNP) | VAF 72/147 reads (49%) | called by muse, mutect2, varscan2
- ZNF541 | c.708C>T p.C236= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as rs748731735, COSV54547366; called by muse, mutect2, varscan2
- AC004890.2 | n.2120C>T | RNA (SNP) | VAF 166/311 reads (53%) | catalogued as rs549201700; called by muse, mutect2, varscan2
- AC104825.1 | n.1632_1634del | RNA (DEL) | VAF 29/200 reads (15%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.187+477T>G | Intron (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- CCNL1 | c.488+1834T>C | Intron (SNP) | VAF 103/258 reads (40%) | called by muse, mutect2, varscan2
- CYLC2 | c.-30T>G | 5'UTR (SNP) | VAF 5/49 reads (10%) | catalogued as COSV66336900; called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630463 C>T | 5'Flank (SNP) | VAF 60/680 reads (9%) | called by muse, mutect2
- EPDR1 | c.-153C>T | 5'UTR (SNP) | VAF 67/227 reads (30%) | called by muse, mutect2, varscan2
- FAT3 | c.13052-602G>A | Intron (SNP) | VAF 97/231 reads (42%) | catalogued as rs747818054; called by muse, mutect2, varscan2
- FOXM1 | c.1267-1687T>G | Intron (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8514T>G | Intron (SNP) | VAF 21/214 reads (10%) | catalogued as rs538434925, COSV69742627; called by muse, varscan2
- GBA3 | c.59-8306A>G | Intron (SNP) | VAF 14/84 reads (17%) | catalogued as rs532279707, COSV69742589; called by muse, varscan2
- GBA3 | c.59-8073T>C | Intron (SNP) | VAF 9/51 reads (18%) | catalogued as rs538774739, COSV69742631; called by muse, mutect2, varscan2
- ILF3 | c.*134A>T | 3'UTR (SNP) | VAF 199/384 reads (52%) | called by muse, mutect2, varscan2
- KLHL3 | c.904-7643A>C | Intron (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- LMF1 | c.503+6840G>A | Intron (SNP) | VAF 242/342 reads (71%) | called by muse, mutect2, varscan2
- MIR520B | n.51C>G | RNA (SNP) | VAF 15/172 reads (9%) | called by muse, mutect2
- MLXIPL | c.1822+42G>A | Intron (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1469557 C>T | 3'Flank (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- OR7A2P | n.305C>A | RNA (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- PNCK | c.-2-237C>T | Intron (SNP) | VAF 41/70 reads (59%) | catalogued as rs1188597771; called by muse, mutect2, varscan2
- PNKD | c.236+1161C>G | Intron (SNP) | VAF 37/293 reads (13%) | called by muse, mutect2, varscan2
- POT1 | c.950-1613_950-1598del | Intron (DEL) | VAF 36/67 reads (54%) | called by mutect2, pindel, varscan2
- PRDM5 | c.865+56C>T | Intron (SNP) | VAF 135/161 reads (84%) | catalogued as rs764175410; called by muse, mutect2, varscan2
- PSCA | c.25+12G>A | Intron (SNP) | VAF 32/281 reads (11%) | called by muse, mutect2, varscan2
- RFTN1 | c.333-6702C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- RNA5-8SP2 | chr16:34159623 G>A | 5'Flank (SNP) | VAF 17/102 reads (17%) | catalogued as rs1342358497; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1670G>A | RNA (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2
- SDHAP2 | n.1410G>A | RNA (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- SF3B3 | c.826-275C>T | Intron (SNP) | VAF 26/65 reads (40%) | catalogued as rs1392171389; called by muse, mutect2, varscan2
- SLC20A2 | c.289+905A>T | Intron (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- SNX17 | c.-81C>G | 5'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- SPEF2 | c.2398+1518C>G | Intron (SNP) | VAF 30/464 reads (6%) | called by muse, mutect2
- SRI | c.511+13A>C | Intron (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
- TENM4 | c.494-287G>A | Intron (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- TPGS2 | chr18:36829110 G>C | 5'Flank (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- VASH1 | c.*563G>C | 3'UTR (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- XIAP | c.*5997G>A | 3'UTR (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- ZFP28 | c.898+53T>G | Intron (SNP) | VAF 38/369 reads (10%) | catalogued as COSV56736922; called by muse, mutect2, varscan2
- ZNF24 | c.568+770A>T | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- ZNF322P1 | n.470G>A | RNA (SNP) | VAF 13/63 reads (21%) | catalogued as rs764771311; called by mutect2, varscan2
